Somatic mutation profile of tumor specimen TARGET-40-NAAGJX-01A (aliquot TARGET-40-NAAGJX-01A-01D) from TARGET case TARGET-40-NAAGJX, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 10.1 years (3,700 days).
Specimen TARGET-40-NAAGJX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de05184b-fcdd-43b2-8a33-d0bff0ef1b54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJX-10A (Blood Derived Normal), aliquot TARGET-40-NAAGJX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3505d8be-f678-4792-9893-0c1bd048e5b9

The open-access MAF lists 54 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 12, Intron 3, 5'Flank 2, Splice Region 2, 5'UTR 1, Splice Site 1, RNA 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADSB | c.34A>G p.S12G | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV62550627; called by muse, mutect2, varscan2
- CCDC112 | c.773A>G p.E258G | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1286772222; called by muse, mutect2, varscan2
- CEP63 | c.1621A>T p.I541F | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT deleterious (0.05); PolyPhen benign (0.172); catalogued as COSV59680205; called by muse, mutect2, varscan2
- DDR1 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749362174; called by muse, mutect2, varscan2
- DENND4A | c.2365G>T p.A789S | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372479600; called by muse, mutect2, varscan2
- DNAAF1 | c.1484C>A p.P495Q | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.899); catalogued as CD144219; called by muse, mutect2, varscan2
- HSD17B4 | c.653C>A p.A218D (on ENST00000414835 / NM_001199291.3; = p.A193D on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754803105; called by mutect2, varscan2
- HSF4 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 87/157 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV50457975; called by muse, mutect2, varscan2
- IMP3 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100145873; called by muse, mutect2
- ZNF563 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs113773973; called by muse, mutect2, varscan2
- ACACB | c.7012C>T p.Q2338* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- ADAMTS13 | c.1441G>C p.A481P | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- AHNAK2 | c.13073A>G p.Q4358R | Missense Mutation (SNP) | VAF 91/228 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ALMS1 | c.6959A>C p.Q2320P | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- CARD14 | c.2668G>A p.A890T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.272); called by muse, mutect2
- CCDC106 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2
- ERC1 | c.2447G>C p.R816P (on ENST00000360905 / NM_178040.4; = p.R788P on NM_178039.4) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- FOLH1 | c.725A>G p.Y242C | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRTM4 | c.639G>T p.E213D | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAML3 | c.3019A>T p.S1007C | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- NRAP | c.4130G>A p.S1377N (on ENST00000359988 / NM_001322945.2; = p.S1342N on NM_006175.4) | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NVL | c.2367-2A>G p.X789_splice | Splice Site (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- PKD1 | c.8752G>A p.A2918T | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PKDREJ | c.3770C>T p.T1257I | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PKP1 | c.1420A>C p.N474H | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLXNB3 | c.5409G>A p.R1803= | Splice Region (SNP) | VAF 21/28 reads (75%) | called by muse, mutect2, varscan2
- RAI1 | c.5660-3C>G | Splice Region (SNP) | VAF 48/1153 reads (4%) | called by muse, mutect2
- SALL3 | c.3230G>T p.G1077V | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TLR6 | c.1360G>T p.V454L | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- TRPM3 | c.4315G>T p.V1439L (on ENST00000357533 / NM_001366142.2; = p.V1294L on NM_020952.6) | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBR1 | c.2108A>G p.D703G | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- UBR5 | c.2272G>T p.A758S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- UTP25 | c.1756A>G p.N586D | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by mutect2, varscan2
- ZBED9 | c.3217G>A p.E1073K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CCNE1 | c.162G>A p.R54= | Silent (SNP) | VAF 370/685 reads (54%) | called by muse, varscan2
- CEMIP2 | c.3168A>G p.T1056= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs1456668223; called by muse, mutect2, varscan2
- GABPB1 | c.765A>G p.E255= | Silent (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- KCNH1 | c.1815G>A p.G605= (on ENST00000271751 / NM_172362.3; = p.G578= on NM_002238.4) | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs760359944; called by muse, mutect2, varscan2
- KDM4A | c.3165G>A p.E1055= | Silent (SNP) | VAF 34/88 reads (39%) | called by muse, mutect2, varscan2
- LRP2BP | c.447T>C p.V149= | Silent (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- MBOAT4 | c.1233G>T p.S411= | Silent (SNP) | VAF 7/84 reads (8%) | called by muse, mutect2
- MYH3 | c.1809C>T p.N603= | Silent (SNP) | VAF 58/129 reads (45%) | catalogued as rs779289839, COSV56866965; called by muse, mutect2, varscan2
- NFAT5 | c.837A>G p.G279= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- PIGC | c.531A>G p.L177= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as rs756094179; called by muse, mutect2, varscan2
- PINX1 | c.708G>T p.T236= | Silent (SNP) | VAF 97/175 reads (55%) | called by muse, mutect2, varscan2
- TRIM65 | c.1038G>A p.L346= | Silent (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501543 G>A | 5'Flank (SNP) | VAF 13/47 reads (28%) | catalogued as rs1271541994; called by muse, mutect2, varscan2
- CNKSR1 | c.947+33G>A | Intron (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- GFAP | c.*8C>A | 3'UTR (SNP) | VAF 27/124 reads (22%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-1249A>G | Intron (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- NDUFV1 | chr11:67604486 G>T | 5'Flank (SNP) | VAF 19/96 reads (20%) | called by muse, mutect2, varscan2
- SEPTIN11 | c.28-507T>C | Intron (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2, varscan2
- TUBB7P | n.126G>A | RNA (SNP) | VAF 10/31 reads (32%) | catalogued as rs782251087; called by muse, varscan2
- XCL2 | c.-8C>T | 5'UTR (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100892263; called by muse, mutect2, varscan2
